Somatic mutation profile of cancer-model specimen HCM-CSHL-0164-C20-85A (3D Organoid; aliquot HCM-CSHL-0164-C20-85A-01D-A77E-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0164-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 51.5 years (18,816 days).
Specimen HCM-CSHL-0164-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83e69fec-9f9a-4a72-8988-883a9534cd96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0164-C20-11A (Solid Tissue Normal), aliquot HCM-CSHL-0164-C20-11A-11D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a860d4f1-611d-4ffe-b822-f58682ab33c9

The open-access MAF lists 177 somatic variants for this specimen: 105 protein-altering or splice-affecting, 51 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 51, Intron 13, Nonsense Mutation 9, RNA 3, 3'UTR 2, Frame Shift Del 2, 5'UTR 2, 5'Flank 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 114/246 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NR3C2 | c.1951C>T p.R651* | Nonsense Mutation (SNP) | VAF 63/129 reads (49%) | catalogued as rs1131691921, CM127494, COSV60987868; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 309/310 reads (100%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY6 | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 125/299 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs55726827; called by muse, mutect2, varscan2
- ADD2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 106/212 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781893870, COSV52469857; called by muse, mutect2, varscan2
- ANK2 | c.5726A>G p.K1909R | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.024); catalogued as rs868828587; called by muse, mutect2, varscan2
- AR | c.1368_1406del p.G461_G473del | In Frame Del (DEL) | VAF 121/265 reads (46%) | catalogued as rs1314410183; called by pindel, varscan2*
- CABP7 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs200796412; called by muse, mutect2, varscan2
- CARD11 | c.2818C>A p.L940I | Missense Mutation (SNP) | VAF 121/383 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV62755943; called by muse, mutect2, varscan2
- CBX2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 360/706 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151114184; called by muse, mutect2, varscan2
- CCDC88C | c.3445G>A p.E1149K | Missense Mutation (SNP) | VAF 197/435 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774584774, COSV66239736; called by muse, mutect2, varscan2
- CEMIP2 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 170/344 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs777253304; called by muse, mutect2, varscan2
- CLEC4G | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs1454674867; called by muse, mutect2, varscan2
- CNTN2 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 195/492 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs758068126; called by muse, mutect2, varscan2
- CNTNAP4 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1328938055; called by muse, mutect2, varscan2
- COL11A1 | c.3829G>A p.E1277K | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs745458984, COSV62191935; called by muse, mutect2, varscan2
- CPA3 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275808254, COSV56045944; called by muse, mutect2, varscan2
- DCC | c.2624C>T p.T875M | Missense Mutation (SNP) | VAF 320/323 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs747051148, COSV59139035; called by muse, mutect2, varscan2
- DUSP16 | c.42G>C p.R14S | Missense Mutation (SNP) | VAF 13/394 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV53806246; called by muse, mutect2
- EBI3 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); catalogued as rs762654891, COSV99696043; called by muse, mutect2, varscan2
- FANK1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 185/186 reads (99%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); catalogued as COSV100904814; called by muse, mutect2, varscan2
- FAT4 | c.3562C>T p.Q1188* | Nonsense Mutation (SNP) | VAF 87/161 reads (54%) | catalogued as rs1336643545, COSV67897636; called by muse, mutect2, varscan2
- FPR3 | c.911T>G p.F304C | Missense Mutation (SNP) | VAF 107/196 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59328946; called by muse, mutect2, varscan2
- GASK1B | c.578C>A p.P193Q | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56706136; called by muse, mutect2
- GSDMC | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 29/304 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs759624672, COSV52696137; called by muse, mutect2
- GTPBP2 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 79/154 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs771927723; called by muse, mutect2, varscan2
- HDAC5 | c.2793dup p.I932Hfs*24 | Frame Shift Ins (INS) | VAF 100/223 reads (45%) | catalogued as rs770174487; called by mutect2, varscan2
- HES6 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 325/722 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV54524916; called by muse, mutect2, varscan2
- IGHV5-51 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 271/572 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs782043169; called by muse, mutect2, varscan2
- KCNA3 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 214/388 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs749760182, COSV63901778; called by muse, mutect2, varscan2
- KCNT1 | c.3424G>A p.E1142K (on ENST00000488444; = p.D1168N on NM_020822.3) | Missense Mutation (SNP) | VAF 99/203 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs747317425, COSV53707605, COSV53711347; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KDM5C | c.2503G>A p.G835S | Missense Mutation (SNP) | VAF 199/489 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs781782813; ClinVar: benign; called by muse, mutect2, varscan2
- NACAD | c.4168G>A p.V1390M | Missense Mutation (SNP) | VAF 195/612 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs1035498664; called by muse, mutect2, varscan2
- NRP2 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 351/722 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs766899842; called by muse, mutect2, varscan2
- NUMA1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 148/272 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs190582413, COSV61191341; called by muse, mutect2, varscan2
- NYAP2 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 176/334 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs759695162; called by muse, mutect2, varscan2
- PAPLN | c.799C>T p.R267* (on ENST00000554301; = p.R240* on NM_173462.4) | Nonsense Mutation (SNP) | VAF 90/170 reads (53%) | catalogued as rs199674160; called by muse, mutect2, varscan2
- PCDH12 | c.2734C>T p.R912W | Missense Mutation (SNP) | VAF 396/397 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574087581, COSV51522153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHGC3 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 128/258 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs753075137; called by muse, mutect2, varscan2
- PGR | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs150584881; called by muse, mutect2, varscan2
- PLEC | c.7511C>T p.T2504M (on ENST00000322810 / NM_201380.4; = p.T2394M on NM_000445.5) | Missense Mutation (SNP) | VAF 267/860 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as rs782618173, COSV59683824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTK2 | c.2941C>T p.R981* | Nonsense Mutation (SNP) | VAF 141/531 reads (27%) | catalogued as rs878926321; called by muse, mutect2, varscan2
- PTMS | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 143/308 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs867073491; called by muse, mutect2, varscan2
- RCVRN | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 80/82 reads (98%) | catalogued as rs142436628, COSV56841284; called by muse, mutect2, varscan2
- RYR3 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 88/172 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs377624442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIN3B | c.3469C>T p.R1157C | Missense Mutation (SNP) | VAF 122/228 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs139041823; called by muse, mutect2, varscan2
- SNCAIP | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV54422659; called by muse, mutect2, varscan2
- SNX8 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 77/277 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs138849540; called by muse, mutect2, varscan2
- SOX11 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 178/456 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58983641; called by muse, mutect2
- SPATA31D1 | c.2782A>T p.I928F | Missense Mutation (SNP) | VAF 91/173 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.159); catalogued as rs888563273; called by muse, mutect2, varscan2
- SPEG | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1238354450; called by muse, mutect2
- SYDE1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 133/268 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.214); catalogued as rs752989406, COSV61442534; called by muse, mutect2, varscan2
- TAFA5 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs1485482271; called by muse, mutect2, varscan2
- TERT | c.2476G>A p.V826I | Missense Mutation (SNP) | VAF 149/290 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as rs1060503009, COSV57211979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEX2 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs369287988; called by muse, mutect2, varscan2
- TLE4 | c.467A>T p.Q156L | Missense Mutation (SNP) | VAF 168/425 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV54639041; called by muse, mutect2, varscan2
- TMPRSS9 | c.2933C>T p.P978L (on ENST00000648592; = p.P944L on NM_182973.2) | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs762861820; called by muse, mutect2
- TWIST1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM000118, CM060097, COSV54250834; called by muse, mutect2
- ZBTB7B | c.137G>A p.R46H (on ENST00000292176; = p.R80H on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 177/394 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.837); catalogued as rs140676784; called by muse, mutect2, varscan2
- ZFC3H1 | c.5966A>T p.H1989L | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66430086; called by muse, mutect2
- ZFHX3 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 118/315 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs370398587; called by muse, mutect2, varscan2
- ZMYM1 | c.2943A>T p.L981F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.637); catalogued as rs751374388; called by muse, mutect2, varscan2
- ZNF7 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.923); catalogued as rs146091107; called by muse, mutect2, varscan2
- ALDH1L2 | c.2662G>C p.D888H | Missense Mutation (SNP) | VAF 116/285 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP2A2 | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 244/496 reads (49%) | called by muse, mutect2, varscan2
- APC | c.4192_4193del p.R1399Ffs*9 | Frame Shift Del (DEL) | VAF 124/192 reads (65%) | called by pindel, varscan2
- BCORL1 | c.3895C>T p.R1299* | Nonsense Mutation (SNP) | VAF 175/175 reads (100%) | called by muse, mutect2, varscan2
- BRWD3 | c.1129T>G p.L377V | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- COL5A2 | c.3701G>A p.G1234E | Missense Mutation (SNP) | VAF 13/340 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.196); called by muse, mutect2
- DCC | c.3498A>C p.E1166D | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.139); called by muse, mutect2
- DNHD1 | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 180/367 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- EFCAB7 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- EFR3A | c.1543A>C p.I515L | Missense Mutation (SNP) | VAF 71/128 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBXW9 | c.808G>T p.V270L (on ENST00000587955; = p.V280L on NM_032301.3) | Missense Mutation (SNP) | VAF 194/438 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- GDPD4 | c.974G>T p.R325I | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- GRAMD2A | c.756A>T p.R252S | Missense Mutation (SNP) | VAF 86/167 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM6 | c.811C>G p.P271A | Missense Mutation (SNP) | VAF 347/700 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- HK3 | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 176/400 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQSEC2 | c.1191T>A p.Y397* (on ENST00000642864 / NM_001111125.3; = p.Y192* on NM_015075.2) | Nonsense Mutation (SNP) | VAF 143/328 reads (44%) | called by muse, mutect2, varscan2
- KHDC1 | c.188C>G p.T63S | Missense Mutation (SNP) | VAF 107/218 reads (49%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- KIF13A | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- KIF4A | c.1342C>G p.Q448E | Missense Mutation (SNP) | VAF 96/198 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LGR5 | c.2555T>A p.I852N | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- LRSAM1 | c.341A>C p.N114T | Missense Mutation (SNP) | VAF 206/461 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MS4A7 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MYH4 | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NFKBIZ | c.1253T>C p.F418S | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2G2 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- OR52L1 | c.361T>G p.F121V | Missense Mutation (SNP) | VAF 202/375 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PASD1 | c.2084A>G p.E695G | Missense Mutation (SNP) | VAF 189/380 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- POLR1D | c.399C>G p.F133L | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC12A9 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 144/324 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC34A2 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SMARCA5 | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SNAPC1 | c.571_577del p.K191* | Frame Shift Del (DEL) | VAF 50/115 reads (43%) | called by mutect2, pindel
- TCF7L2 | c.1455G>T p.K485N (on ENST00000355995 / NM_001367943.1; = p.K462N on NM_030756.5) | Missense Mutation (SNP) | VAF 107/111 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- TNKS2 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRMT44 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 83/213 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WNK4 | c.2747C>G p.P916R | Missense Mutation (SNP) | VAF 137/237 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZFHX4 | c.3177G>C p.K1059N | Missense Mutation (SNP) | VAF 126/413 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- ZFP37 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF106 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.328); called by muse, mutect2
- ZNF292 | c.6075G>C p.L2025F | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ZNF747 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 261/512 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ZNF831 | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCB11 | c.678G>A p.S226= | Silent (SNP) | VAF 148/274 reads (54%) | catalogued as rs777962265; called by muse, mutect2, varscan2
- ABCC12 | c.2604C>A p.T868= | Silent (SNP) | VAF 232/585 reads (40%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.189G>T p.R63= | Silent (SNP) | VAF 22/408 reads (5%) | called by muse, mutect2
- AMD1 | c.261G>A p.L87= | Silent (SNP) | VAF 20/276 reads (7%) | catalogued as rs1284561715, COSV64386891; called by muse, mutect2
- AMD1 | c.402A>C p.I134= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- ANK2 | c.2508T>A p.P836= | Silent (SNP) | VAF 15/238 reads (6%) | called by muse, mutect2
- APH1A | c.369C>G p.L123= | Silent (SNP) | VAF 8/169 reads (5%) | catalogued as COSV52530477; called by muse, mutect2
- B3GNT7 | c.597C>G p.L199= | Silent (SNP) | VAF 124/237 reads (52%) | called by muse, mutect2, varscan2
- BCOR | c.3642T>C p.L1214= (on ENST00000378444 / NM_001123385.2; = p.L1180= on NM_017745.6) | Silent (SNP) | VAF 261/500 reads (52%) | called by muse, mutect2, varscan2
- CHRNA7 | c.1293G>A p.P431= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs775002981, COSV100181613; called by mutect2, varscan2
- CLOCK | c.498T>A p.V166= | Silent (SNP) | VAF 42/104 reads (40%) | called by muse, mutect2, varscan2
- CNOT2 | c.*4_*23del | Silent (DEL) | VAF 7/104 reads (7%) | called by mutect2, pindel
- COL5A1 | c.4707G>T p.P1569= | Silent (SNP) | VAF 81/175 reads (46%) | catalogued as rs370009851, COSV65668232; called by muse, mutect2, varscan2
- CRB2 | c.681C>T p.C227= | Silent (SNP) | VAF 203/406 reads (50%) | catalogued as COSV63504673; called by muse, mutect2, varscan2
- DDX6 | c.546A>G p.Q182= | Silent (SNP) | VAF 18/415 reads (4%) | catalogued as rs782712468, COSV50589477; called by muse, mutect2
- EIF1 | c.135T>C p.T45= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs1407402470, COSV60422169; called by muse, mutect2
- EIF4E2 | c.723G>A p.R241= | Silent (SNP) | VAF 17/334 reads (5%) | called by muse, mutect2
- EIF5A | c.87C>T p.G29= | Silent (SNP) | VAF 32/529 reads (6%) | called by muse, mutect2
- FADS3 | c.1167C>T p.F389= | Silent (SNP) | VAF 199/359 reads (55%) | called by muse, mutect2, varscan2
- FUS | c.777T>C p.R259= | Silent (SNP) | VAF 24/600 reads (4%) | catalogued as COSV54215435; called by muse, mutect2
- GASK1B | c.579A>T p.P193= | Silent (SNP) | VAF 20/294 reads (7%) | called by muse, mutect2
- HMX1 | c.477G>A p.A159= | Silent (SNP) | VAF 18/291 reads (6%) | catalogued as rs1427347282; called by muse, mutect2
- HNRNPD | c.324T>C p.T108= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV58312762; called by muse, mutect2
- HPSE2 | c.729T>C p.S243= | Silent (SNP) | VAF 8/250 reads (3%) | called by muse, mutect2
- HSPG2 | c.1683C>T p.P561= | Silent (SNP) | VAF 94/183 reads (51%) | catalogued as rs779806460; called by muse, mutect2, varscan2
- ILF3 | c.579C>T p.D193= | Silent (SNP) | VAF 20/294 reads (7%) | catalogued as COSV51553946; called by muse, mutect2
- KANSL2 | c.1185T>C p.A395= | Silent (SNP) | VAF 14/302 reads (5%) | catalogued as COSV63479288; called by muse, mutect2
- KDM2A | c.747G>A p.L249= | Silent (SNP) | VAF 13/315 reads (4%) | called by muse, mutect2
- MINDY3 | c.132A>G p.E44= | Silent (SNP) | VAF 15/215 reads (7%) | called by muse, mutect2
- MKLN1 | c.2106C>T p.H702= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as rs1368274995; called by muse, mutect2
- MMP3 | c.1155G>A p.V385= | Silent (SNP) | VAF 125/278 reads (45%) | called by muse, mutect2, varscan2
- MTA1 | c.1245T>C p.R415= | Silent (SNP) | VAF 16/422 reads (4%) | catalogued as COSV58755542; called by muse, mutect2
- MUC16 | c.6453T>A p.T2151= | Silent (SNP) | VAF 11/205 reads (5%) | called by muse, mutect2
- NFIA | c.63C>T p.L21= | Silent (SNP) | VAF 8/141 reads (6%) | catalogued as rs1313618315; called by muse, mutect2
- NPTN | c.171C>T p.S57= | Silent (SNP) | VAF 18/340 reads (5%) | catalogued as rs1052757996, COSV54736565; called by muse, mutect2
- PAX3 | c.999G>A p.P333= | Silent (SNP) | VAF 228/484 reads (47%) | catalogued as rs913226154, COSV100399897; called by muse, varscan2
- PCLO | c.6528C>A p.V2176= | Silent (SNP) | VAF 80/151 reads (53%) | catalogued as COSV61629821; called by muse, mutect2, varscan2
- RGMB | c.999G>A p.L333= (on ENST00000513185 / NM_001366508.1; = p.L374= on NM_001012761.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 38/256 reads (15%) | catalogued as COSV100374746; called by muse, mutect2, varscan2
- RTN1 | c.1101G>A p.S367= | Silent (SNP) | VAF 154/345 reads (45%) | catalogued as rs912145580, COSV50720712; called by muse, mutect2, varscan2
- SEC24B | c.2985A>G p.V995= | Silent (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
- SEC61A2 | c.567G>A p.E189= | Silent (SNP) | VAF 9/284 reads (3%) | called by muse, mutect2
- SETD5 | c.450T>C p.Y150= | Silent (SNP) | VAF 12/199 reads (6%) | catalogued as COSV56712199; called by muse, mutect2
- SLC5A1 | c.66C>T p.L22= | Silent (SNP) | VAF 30/839 reads (4%) | called by muse, mutect2
- SYT9 | c.243G>A p.P81= | Silent (SNP) | VAF 162/389 reads (42%) | catalogued as rs752667061, COSV59618348; called by muse, mutect2, varscan2
- TFPI | c.423T>C p.Y141= | Silent (SNP) | VAF 52/96 reads (54%) | catalogued as rs1432928818; called by muse, mutect2, varscan2
- TNFRSF18 | c.573G>A p.Q191= | Silent (SNP) | VAF 304/555 reads (55%) | catalogued as rs749873829; called by muse, mutect2, varscan2
- TRIM72 | c.1281C>T p.Y427= | Silent (SNP) | VAF 31/339 reads (9%) | catalogued as rs969863188; called by muse, mutect2
- UHRF1 | c.1608G>T p.V536= (on ENST00000612630 / NM_001290050.1; = p.V549= on NM_013282.4) | Silent (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- UNC79 | c.321C>T p.P107= | Silent (SNP) | VAF 24/526 reads (5%) | catalogued as rs1372490934, COSV56393927; called by muse, mutect2
- VPS13D | c.9162G>C p.V3054= | Silent (SNP) | VAF 116/254 reads (46%) | called by muse, mutect2, varscan2
- ZNF544 | c.1503C>T p.F501= | Silent (SNP) | VAF 83/199 reads (42%) | catalogued as rs1179656357; called by muse, mutect2, varscan2
- ATG13 | c.790-793C>T | Intron (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- ATRX | c.4810-47_4810-46insG | Intron (INS) | VAF 46/122 reads (38%) | called by mutect2, pindel, varscan2
- BRD2 | c.333+265T>C | Intron (SNP) | VAF 10/278 reads (4%) | called by muse, mutect2
- BRD2 | c.333+267G>T | Intron (SNP) | VAF 10/283 reads (4%) | called by muse, mutect2
- CCDC51 | chr3:48440392 G>A | 5'Flank (SNP) | VAF 192/391 reads (49%) | called by muse, mutect2, varscan2
- COL16A1 | c.2772+14A>C | Intron (SNP) | VAF 30/469 reads (6%) | called by muse, mutect2
- CST9LP1 | n.183G>C | RNA (SNP) | VAF 32/105 reads (30%) | called by muse, mutect2, varscan2
- HOXA11 | c.-1A>G | 5'UTR (SNP) | VAF 26/1026 reads (3%) | catalogued as COSV99136147; called by muse, mutect2
- LINC01973 | n.1696G>A | RNA (SNP) | VAF 284/600 reads (47%) | catalogued as rs372748711; called by muse, mutect2, varscan2
- LUC7L3 | c.*33+84A>G | Intron (SNP) | VAF 13/251 reads (5%) | catalogued as COSV53585599; called by muse, mutect2
- MBD5 | c.2845+621A>C | Intron (SNP) | VAF 7/124 reads (6%) | catalogued as COSV101290117; called by muse, mutect2
- NAP1L1 | c.1090-210A>C | Intron (SNP) | VAF 10/139 reads (7%) | called by muse, mutect2
- PRPF39 | c.450+205A>C | Intron (SNP) | VAF 11/251 reads (4%) | called by muse, mutect2
- SENP1 | c.221-227A>C | Intron (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- SETD5 | c.178-157A>G | Intron (SNP) | VAF 13/235 reads (6%) | catalogued as COSV56712180; called by muse, mutect2
- SHLD2P3 | n.2496C>T | RNA (SNP) | VAF 18/290 reads (6%) | called by muse, mutect2
- SYT6 | c.*106C>T | 3'UTR (SNP) | VAF 124/237 reads (52%) | catalogued as rs1457051114; called by muse, mutect2, varscan2
- TBC1D4 | c.-43_-35del | 5'UTR (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- TMEM165 | c.433+60C>T | Intron (SNP) | VAF 132/276 reads (48%) | called by muse, mutect2, varscan2
- TRIP4 | c.*8G>A | 3'UTR (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- UBAP2L | c.2902+1467G>C | Intron (SNP) | VAF 8/230 reads (3%) | catalogued as COSV55167640; called by muse, mutect2
